Gene-level copy-number profile of tumor specimen MP2PRT-PAVYKW-TBP1-A from MP2PRT case MP2PRT-PAVYKW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 9.3 years (3,415 days).
Specimen MP2PRT-PAVYKW-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 52441479-6273-4bbd-ad43-c76d599d4981.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVYKW-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/3d4f176c-f806-47e2-a56d-f5abcdb0b0d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 167; copy number 2: 37,955; copy number 3: 19,493; copy number 4: 718.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,221,698–89,234,912, 2 genes (within-gene range 0–1): IGKV2-28, IGKV2-29.
- chr9:20,999,509–23,826,337, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 167. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
